Somatic mutation profile of tumor specimen TCGA-LN-A5U5-01A (aliquot TCGA-LN-A5U5-01A-21D-A28B-09) from TCGA case TCGA-LN-A5U5, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 57.5 years (20,993 days).
Specimen TCGA-LN-A5U5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84c17387-ec5c-43c1-99be-77a3294bf996.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A5U5-10A (Blood Derived Normal), aliquot TCGA-LN-A5U5-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f189ca9-be5a-4816-a9f3-354a23992b83

The open-access MAF lists 61 somatic variants for this specimen: 43 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 17, Frame Shift Del 3, Nonsense Mutation 3, In Frame Del 1, Splice Region 1, Frame Shift Ins 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.101_121del p.R34_S40del | In Frame Del (DEL) | VAF 38/60 reads (63%) | hotspot (GDC flag); called by mutect2, pindel, varscan2*
- AK8 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs376201961; called by muse, mutect2, varscan2
- CYTH3 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV100641509; called by muse, mutect2, varscan2
- ELP5 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100020922; called by muse, mutect2, varscan2
- ENPP3 | c.2083C>G p.P695A | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62953191; called by muse, mutect2, varscan2
- EPB41L4A | c.1270T>C p.Y424H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1312291935; called by muse, mutect2, varscan2
- H2BC9 | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs1352348146; called by muse, mutect2, varscan2
- KIAA0319 | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749156433, COSV65497069; called by muse, mutect2, varscan2
- KRTAP11-1 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV99081946; called by muse, mutect2, varscan2
- RAB2A | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52914502; called by muse, mutect2, varscan2
- RPE65 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV52017509; called by muse, mutect2, varscan2
- TECTA | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs759694570; called by muse, mutect2, varscan2
- TLE1 | c.237T>G p.T79= | Splice Region (SNP) | VAF 5/21 reads (24%) | catalogued as rs771286660; called by muse, mutect2, varscan2
- TMCO4 | c.1115T>G p.V372G | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772635020; called by muse, mutect2, varscan2
- TP53 | c.686del p.C229Lfs*18 | Frame Shift Del (DEL) | VAF 82/132 reads (62%) | catalogued as COSV52670028, COSV52746159, COSV52816928, COSV53136088; called by mutect2, pindel, varscan2
- ABI2 | c.562G>T p.G188W (on ENST00000295851 / NM_001375719.1; = p.G182W on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AK8 | c.688A>G p.I230V | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- C3 | c.3404A>G p.N1135S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTDSP1 | c.352G>C p.V118L | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- CXXC1 | c.1040_1042dup p.R347dup | In Frame Ins (INS) | VAF 11/24 reads (46%) | called by mutect2, pindel, varscan2
- DPH5 | c.776del p.I259Nfs*9 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- EHMT1 | c.1621A>C p.M541L | Missense Mutation (SNP) | VAF 64/87 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- FILIP1L | c.2591C>A p.P864H (on ENST00000354552 / NM_182909.3; = p.P624H on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRRS1 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IDH1 | c.762G>A p.M254I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- INSC | c.1384C>A p.Q462K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.137); called by muse, mutect2
- KCNN2 | c.222C>G p.N74K (on ENST00000264773; = p.N286K on NM_021614.4) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- KMT2D | c.15371dup p.M5124Ifs*14 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- KMT2D | c.11572C>T p.Q3858* | Nonsense Mutation (SNP) | VAF 50/101 reads (50%) | called by muse, mutect2, varscan2
- MAMDC2 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- NOP14 | c.915_924del p.V306Qfs*9 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- PNOC | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POU6F2 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- RGL1 | c.1228A>G p.M410V (on ENST00000360851 / NM_001297672.2; = p.M445V on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SALL1 | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SKOR1 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- STAB1 | c.4707C>A p.C1569* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- STXBP6 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TEX14 | c.2865G>T p.W955C (on ENST00000240361 / NM_001201457.2; = p.W949C on NM_031272.5) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TOP2A | c.1161C>A p.S387R | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TP53BP1 | c.2050A>C p.M684L | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSC2 | c.1225G>T p.E409* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- UNC5D | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALG1 | c.111G>A p.A37= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs1464493808; called by muse, mutect2, varscan2
- B3GLCT | c.1044G>T p.V348= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100587405; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4059T>C p.A1353= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- CX3CL1 | c.261G>A p.Q87= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs373682759; called by muse, mutect2, varscan2
- DNAH14 | c.939C>A p.S313= (on ENST00000445597; = p.S186= on NM_144989.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- H3-5 | c.12C>G p.T4= | Silent (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- HTR3E | c.144G>A p.V48= (on ENST00000415389 / NM_001256613.1; = p.V63= on NM_182589.2) | Silent (SNP) | VAF 27/160 reads (17%) | called by muse, mutect2, varscan2
- OLAH | c.114C>A p.G38= | Silent (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- OR6C2 | c.705C>T p.A235= | Silent (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- PI4KB | c.1299C>T p.P433= (on ENST00000368873 / NM_001369623.1; = p.P445= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as rs764752078, COSV99649900; called by muse, mutect2, varscan2
- PIK3C2A | c.5028A>G p.K1676= | Silent (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- SGIP1 | c.270C>T p.P90= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs766048418, COSV99391709; called by muse, mutect2
- SUPT5H | c.2007C>T p.I669= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs1225660142; called by muse, mutect2, varscan2
- TAOK2 | c.3201C>A p.G1067= | Silent (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- TEPP | c.516G>A p.A172= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs759241646, COSV52043366, COSV99333239; called by muse, mutect2, varscan2
- TNIP1 | c.216G>T p.L72= | Silent (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- TTN | c.20397C>T p.C6799= (on ENST00000591111; = p.C5872= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs750661972, COSV60201673; called by muse, mutect2, varscan2
- MIR514A2 | n.29T>G | RNA (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
